Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAF0, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAF0-01A (Primary Tumor).

Department of Pathology

ICD-O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
Jw 2/3/14

Direct dial

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 5 cm; tumor confined to testis in available slides; no angio-invasion present; invasion in rete testis present.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Criteria	Jw 11/8/14	Yes	No

Source: NCI Genomic Data Commons file 71ad6ba8-70cb-4114-96a7-92a7154df9f2 (TCGA-2G-AAF0-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).